Somatic mutation profile of tumor specimen TCGA-G9-6354-01A (aliquot TCGA-G9-6354-01A-11D-A30X-08) from TCGA case TCGA-G9-6354, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 55.9 years (20,403 days).
Specimen TCGA-G9-6354-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7af67a39-fb6b-4029-8640-6832892c433f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6354-10A (Blood Derived Normal), aliquot TCGA-G9-6354-10A-01D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64ed1aac-7058-47e3-8efc-9165a8f88004

The open-access MAF lists 27 somatic variants for this specimen: 23 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 19, Silent 4, Nonsense Mutation 2, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEMIP2 | c.1822G>A p.E608K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV65488375; called by muse, mutect2
- DTX4 | c.1231A>G p.I411V | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57093078; called by muse, mutect2, varscan2
- FAM71A | c.76G>T p.G26W | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54236388; called by mutect2, varscan2
- GMPR2 | c.135C>A p.Y45* (on ENST00000355299 / NM_001351022.2; = p.Y63* on NM_016576.5) | Nonsense Mutation (SNP) | VAF 14/65 reads (22%) | catalogued as COSV51661154; called by muse, mutect2, varscan2
- GPS2 | c.318-1G>A p.X106_splice | Splice Site (SNP) | VAF 6/49 reads (12%) | catalogued as COSV59748218, COSV59751846; called by muse, mutect2
- HTR1E | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375047597; called by muse, mutect2
- MYCBP2 | c.11981A>T p.Y3994F (on ENST00000357337; = p.Y4032F on NM_015057.5) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV62029726; called by muse, mutect2, varscan2
- NUP107 | c.801G>A p.Q267= | Splice Region (SNP) | VAF 9/76 reads (12%) | catalogued as COSV57496319; called by muse, mutect2
- OR4C6 | c.908G>T p.W303L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs1429134194, COSV58604249; called by muse, mutect2, varscan2
- P2RY8 | c.992C>T p.T331M | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs776454714, COSV67177190; called by muse, mutect2
- PRKAR1B | c.438G>C p.R146S | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.542); catalogued as COSV64319377; called by muse, mutect2, varscan2
- RARB | c.250G>A p.V84M (on ENST00000383772 / NM_001290216.2; = p.V77M on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV58069193; called by muse, mutect2
- RUSF1 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1451015824, COSV59131782; called by muse, mutect2
- SCD | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 23/219 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV64853342; called by muse, mutect2, varscan2
- SHROOM4 | c.2690T>C p.V897A | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.058); catalogued as COSV56793413; called by muse, mutect2, varscan2
- TAAR6 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 102/343 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs770532856, COSV51584340; called by muse, mutect2, varscan2
- THSD7B | c.2459C>T p.T820M | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs568467115, COSV55677825; called by muse, mutect2, varscan2
- VN1R2 | c.562G>A p.V188M | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as rs1018378963, COSV59039021; called by muse, mutect2, varscan2
- WASHC2C | c.571A>G p.K191E | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV60492371; called by muse, mutect2
- ZFHX4 | c.7660A>T p.S2554C | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV51474738; called by muse, mutect2, varscan2
- ZNF19 | c.202A>G p.R68G | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1473621672, COSV55508349; called by muse, mutect2, varscan2
- CHD5 | c.496C>T p.Q166* | Nonsense Mutation (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2
- SLC9C1 | c.1219G>T p.V407L | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2
- PLEKHG1 | c.183G>A p.P61= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as rs145506185; called by muse, mutect2, varscan2
- QARS1 | c.1548C>T p.L516= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as rs1004767154, COSV60275645; called by muse, mutect2, varscan2
- TBC1D19 | c.252T>A p.P84= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as COSV53519165; called by muse, mutect2
- TRPA1 | c.879G>A p.S293= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as rs377547475; called by muse, mutect2, varscan2
